Gene-level copy-number profile of tumor specimen ALCH-B3JK-TTP1-A from ALCHEMIST case ALCH-B3JK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.3 years (22,385 days).
Specimen ALCH-B3JK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a762fca0-15c6-4bd7-90cc-b23cce1e95fb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3JK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/eb53f9e8-8d43-4a13-bac3-8c7ab0080b8b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 19,900; copy number 2: 30,202; copy number 3: 5,163; copy number 4: 2,996; copy number 5: 9; copy number 6: 1; copy number 8: 50; copy number 10: 2; copy number 19: 1.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,382,487–7,389,754, 1 gene (within-gene range 0–2): CAMTA1-AS2.
- chr2:232,343,116–232,351,309, 2 genes (within-gene range 0–2): NRBF2P6, ECEL1P3.
- chr2:232,456,125–232,460,753, 1 gene: ALPI.
- chr4:8,846,076–8,871,839, 2 genes: HMX1, AC116612.1.
- chr5:171,345,343–171,457,626, 9 genes: AC091980.1, RN7SL339P, RPSAP71, SNORA70J, RPL10P8, MIR3912, NPM1, FGF18, AC093246.1.
- chr5:173,314,713–173,329,503, 1 gene: STC2.
- chr5:174,561,776–174,730,896, 4 genes: SUMO2P6, AC108112.1, HIGD1AP3, MSX2.
- chr5:174,923,090–174,923,945, 1 gene (within-gene range 0–1): NIFKP2.
- chr5:176,647,387–176,743,871, 4 genes: TSPAN17, AC113391.1, AC113391.2, LINC01574.
- chr5:178,055,604–178,187,371, 6 genes: AC136632.1, N4BP3, RMND5B, NHP2, AC136632.2, GMCL2.
- chr5:178,208,471–178,232,802, 1 gene (within-gene range 0–2): PHYKPL.
- chr5:178,344,843–178,378,220, 3 genes (within-gene range 0–1): AC136601.2, AC136601.1, RN7SL646P.
- chr5:179,377,505–179,492,157, 5 genes: AC109479.3, AC109479.1, AC109479.2, AC136628.1, U4.
- chr7:5,592,816–5,606,655, 1 gene: FSCN1.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr9:61,665,579–61,666,386, 1 gene: AL935212.2.
- chr9:130,444,961–130,501,274, 1 gene: ASS1.
- chr11:63,985,853–64,001,811, 1 gene (within-gene range 0–1): OTUB1.
- chr11:70,646,165–70,872,368, 5 genes (within-gene range 0–1): SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664.
- chr13:50,994,511–51,080,862, 2 genes: GUCY1B2, RNA5SP29.
- chr17:142,789–386,254, 7 genes: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3.
- chr19:453,134–474,983, 2 genes (within-gene range 0–1): RNA5SP462, ODF3L2.
- chr22:18,733,914–18,757,906, 1 gene: FAM230E.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 63 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:42,176,539–43,389,808, 50 genes, copy number 8: FOXJ3, AC096540.1, RIMKLA, AL513331.1, ZMYND12, PPCS, CCDC30, RPS3AP11, TMSB4XP1, RNU6-536P, AL445669.1, PPIH, AC098484.4, AC098484.2, YBX1, CLDN19, P3H1, C1orf50, AC098484.3, AC098484.1, TMEM269, SVBP, ERMAP, AL512353.1, ZNF691, AL512353.2, MKRN8P, ATP6V1E1P1, SLC2A1, ATP6V0CP4, SLC2A1-AS1, AC099795.1, RNU6-880P, AL161637.1, FAM183A, EBNA1BP2, MIR6733, CFAP57, RNA5SP46, TMEM125, C1orf210, TIE1, MPL, AL139289.2, AL139289.1, CDC20, ELOVL1, MIR6734, MED8, MED8-AS1.
- chr1:234,629,311–234,647,571, 2 genes, copy number 5 (within-gene range 4–5): LINC00184, AL160408.5.
- chr8:143,915,153–143,976,734, 1 gene, copy number 6 (within-gene range 3–6): PLEC.
- chr8:144,051,266–144,063,965, 2 genes, copy number 10 (within-gene range 4–10): OPLAH, MIR6846.
- chr16:975,761–986,979, 2 genes, copy number 5 (within-gene range 3–5): CEROX1, SOX8.
- chr16:89,217,703–89,237,141, 2 genes, copy number 5: ZNF778, AC009113.2.
- chr19:1,009,648–1,021,628, 3 genes, copy number 5 (within-gene range 3–5): TMEM259, AC004528.2, RNU6-2.
- chr22:18,650,023–18,653,617, 1 gene, copy number 19: PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 17,565. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
